Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACL, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACL-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo : 1

GROSS:

1. Specimen:

Liver: 11.0 x 10.0 x 4.3 cm, unfixed

Gallbladder: 6.0 cm in length, 3.0 cm in diameter,
0.2 cm in wall thickness, unfixed

2. Tumor location: segment 8

Tumor number: one

Tumor size: 3.5 x 3.3 x 3.3 cm

3. Satellite nodule: no

4. Gross type

HCC: expanding nodular

5. Tumor necrosis: yes(20 %)

6. Hemorrhage/peliosis: no

7. Portal vein invasion: no

8. Bile duct invasion: no

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0
JW 5/19/14

Gross photo present.

Blocks

T1-4, TB, tumor mass x 5

NB, A, non-tumorous lesion x 2

RM, resection margin x 1

GB, gallbladder x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes

1-1. Differentiation

The worst differentiation III

The major differentiation III

1-2. Histologic type: trabecular

1-3. Cell type: hepatic

1-4. Fatty change: no

5. Fibrous capsule formation: partial capsule

6. Capsular infiltration: no

7. Septum formation: no

[page 2 of 2]
8. Surgical resection margin invasion: no, margin of the clearance (0.2 cm)
9. Serosal invasion: no
10. Portal vein invasion: no
11. Bile duct invasion: no
12. Hepatic vein invasion: no
13. Hepatic artery invasion: no
14. Microvessel invasion: no
15. Intrahepatic metastasis: no
16. Multicentric occurrence: no

liver,ectomy,hepatocellular carcinoma,chronic hepatitis
T56000, P10, M81703, MD0522
gallbladder,ectomy,chronic cholecystitis
T57000, P10, M43005

DIAGNOSIS:

Liver, segment 8, segmentectomy:
Hepatocellular carcinoma, moderately differentiated
Chronic hepatitis with impending cirrhosis
Gallbladder, cholecystectomy:
Chronic cholecystitis

NOTE: Recommend to order immunohistochemistry (CK7, hepatocyte, p53, Ki-67) and special stain (mucicarmin stain).

Suggestion :

Source: NCI Genomic Data Commons file 38afbae4-1290-4876-a365-37dfff988a76 (TCGA-DD-AACL.E390B088-3CB5-45A7-B679-7995BE7B00F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).